Somatic mutation profile of tumor specimen TCGA-73-4675-01A (aliquot TCGA-73-4675-01A-01D-1265-08) from TCGA case TCGA-73-4675, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.2 years (21,614 days).
Specimen TCGA-73-4675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72725611-02d2-4c38-837a-249a9eb41373.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4675-11A (Solid Tissue Normal), aliquot TCGA-73-4675-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64cd7216-82b7-4576-8b36-e68eb05e8a68

The open-access MAF lists 77 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 42, Silent 19, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 3, In Frame Del 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NDP | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs104894870, CM920497, COSV65204039; ClinVar: pathogenic; called by muse, mutect2
- AIPL1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV51506891, COSV51506998; called by muse, mutect2, varscan2
- AKAP13 | c.8092C>G p.P2698A (on ENST00000394518 / NM_007200.5; = p.P2702A on NM_006738.6) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV63472147; called by muse, mutect2
- ARHGAP27 | c.2135G>T p.R712L (on ENST00000428638 / NM_001282290.1; = p.R371L on NM_199282.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV104424363, COSV65359018; called by muse, mutect2
- ARID2 | c.1120+1G>A p.X374_splice | Splice Site (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100537301, COSV57617079; called by muse, mutect2, varscan2
- BPIFB3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV64958310; called by muse, mutect2, varscan2
- CGREF1 | c.883C>A p.Q295K (on ENST00000260595; = p.Q312K on NM_006569.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV99564949; called by muse, varscan2
- CSH1 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760583471, COSV60241797, COSV60243135; called by muse, mutect2, varscan2
- DCHS1 | c.6448G>A p.G2150R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV55040502; called by muse, mutect2
- DVL3 | c.1198+1G>T p.X400_splice | Splice Site (SNP) | VAF 28/171 reads (16%) | catalogued as COSV57458726; called by muse, mutect2, varscan2
- EPB41L4A | c.1586A>T p.D529V | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV54883233; called by muse, mutect2, varscan2
- EPHX3 | c.989A>G p.H330R | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV55656902; called by muse, mutect2, varscan2
- FAM135B | c.3875T>C p.F1292S | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52758862; called by muse, mutect2, varscan2
- FBN3 | c.2438G>T p.W813L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54476018; called by muse, mutect2, varscan2
- FCGR3B | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV54212764; called by muse, mutect2, varscan2
- FSTL5 | c.894T>C p.N298= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as rs776408932, COSV60197392; called by muse, varscan2
- GH2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 141/404 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs377217606; called by muse, mutect2, varscan2
- GTF3C5 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100565224; called by muse, mutect2, varscan2
- HECTD3 | c.1908G>T p.K636N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64671079; called by muse, mutect2, varscan2
- IGHMBP2 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.163); catalogued as COSV54827117; called by muse, mutect2, varscan2
- IGKV1-5 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs376732280; called by muse, mutect2, varscan2
- IGSF9B | c.3524C>G p.P1175R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV58073164; called by muse, mutect2, varscan2
- INTS5 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.33); catalogued as COSV57954025; called by muse, mutect2, varscan2
- ITGAV | c.2906A>T p.E969V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV99654165; called by muse, mutect2, varscan2
- KIF1B | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV55817881; called by muse, mutect2, varscan2
- KLHL38 | c.1366A>G p.R456G | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1563591884, COSV58089618; called by muse, mutect2, varscan2
- LAMB2 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59738792; called by muse, mutect2, varscan2
- LAMB2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV59738801; called by muse, varscan2
- LLGL2 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV51418502; called by muse, mutect2, varscan2
- MIA3 | c.1226A>T p.E409V | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV60519330; called by muse, mutect2, varscan2
- MUC16 | c.13745C>A p.S4582* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV67459090, COSV67502311; called by muse, mutect2, varscan2
- MYPN | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV62738485, COSV62741355; called by muse, mutect2, varscan2
- NSRP1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55936060; called by muse, mutect2, varscan2
- OR10A6 | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468303977, COSV100564233; called by muse, mutect2, varscan2
- OR8G5 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100422193; called by muse, mutect2, varscan2
- OSBPL6 | c.2013+2T>C p.X671_splice | Splice Site (SNP) | VAF 28/374 reads (7%) | catalogued as COSV99506412; called by muse, mutect2
- PEG3 | c.2800A>T p.K934* | Nonsense Mutation (SNP) | VAF 63/185 reads (34%) | catalogued as COSV55651608; called by muse, mutect2, varscan2
- PPP2R2C | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 78/166 reads (47%) | catalogued as COSV58675036, COSV58677603; called by muse, mutect2, varscan2
- SELENOI | c.837G>C p.W279C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as COSV99564129; called by muse, mutect2
- SKOR1 | c.2780A>G p.Y927C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1007183357, COSV58250791; called by muse, mutect2, varscan2
- SLC13A1 | c.1079T>G p.L360R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52018079; called by muse, mutect2, varscan2
- STAC | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV56219974, COSV99829785; called by muse, mutect2, varscan2
- STING1 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV58173678; called by muse, mutect2, varscan2
- STK31 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63459799, COSV63460227; called by muse, mutect2, varscan2
- TBX18 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV63738627; called by muse, mutect2, varscan2
- TOGARAM1 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV61889571; called by muse, mutect2, varscan2
- TTN | c.5971C>A p.P1991T (on ENST00000591111; = p.P1945T on NM_003319.4) | Missense Mutation (SNP) | VAF 26/276 reads (9%) | PolyPhen benign (0); catalogued as COSV60417312; called by muse, mutect2
- WDR35 | c.2546C>T p.A849V (on ENST00000345530 / NM_001006657.2; = p.A838V on NM_020779.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55608020; called by muse, mutect2, varscan2
- WDR64 | c.1985T>C p.I662T | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV63801426; called by muse, mutect2, varscan2
- ZNF875 | c.423T>G p.S141R | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); catalogued as COSV100183006; called by muse, mutect2, varscan2
- ARHGEF26 | c.50del p.L17Cfs*31 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- EDEM3 | c.920dup p.D308Rfs*2 | Frame Shift Ins (INS) | VAF 51/98 reads (52%) | called by mutect2, pindel, varscan2
- NLRC5 | c.2859del p.Q955Rfs*20 | Frame Shift Del (DEL) | VAF 67/186 reads (36%) | called by mutect2, pindel, varscan2
- RIT1 | c.248_253del p.T83_A84del | In Frame Del (DEL) | VAF 38/63 reads (60%) | called by mutect2, pindel, varscan2
- SCAF8 | c.430dup p.T144Nfs*33 | Frame Shift Ins (INS) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- SYT4 | c.110del p.C37Sfs*31 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- TANGO6 | c.675del p.G226Vfs*15 | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | called by mutect2, pindel, varscan2
- ZNF513 | c.1053_1064del p.P352_P355del | In Frame Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel
- ADCY8 | c.942G>A p.A314= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV53932808; called by muse, varscan2
- C7 | c.537G>T p.L179= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs777704541, COSV57482627; called by muse, varscan2
- CRELD2 | c.735G>A p.Q245= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100077818; called by muse, mutect2, varscan2
- FAF1 | c.1743C>T p.P581= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV65645205; called by muse, mutect2, varscan2
- HIPK3 | c.2988G>C p.V996= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV57566656; called by muse, mutect2, varscan2
- ITGB2 | c.1218C>T p.Y406= (on ENST00000302347; = p.Y382= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/195 reads (19%) | catalogued as rs61737080; called by muse, mutect2, varscan2
- KLK15 | c.294C>T p.Y98= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs981385274, COSV56827447; called by muse, mutect2, varscan2
- MECOM | c.1461A>T p.S487= (on ENST00000468789 / NM_001105078.4; = p.S675= on NM_004991.4) | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV52958787; called by muse, mutect2, varscan2
- MUC5B | c.4902G>A p.T1634= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs531819682, COSV101499990; called by mutect2, varscan2
- MUC5B | c.10932C>T p.C3644= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV101499991; called by muse, mutect2, varscan2
- NAV1 | c.3924G>T p.S1308= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV55228096; called by muse, mutect2, varscan2
- NR1H3 | c.870G>A p.L290= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs1402975388, COSV68008289; called by muse, mutect2, varscan2
- PSG1 | c.243A>G p.S81= | Silent (SNP) | VAF 195/499 reads (39%) | catalogued as COSV54959353; called by muse, mutect2, varscan2
- PTGS1 | c.1209C>T p.Y403= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs1338200131, COSV56295328; called by muse, mutect2, varscan2
- RNF139 | c.282G>A p.L94= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as COSV52682784; called by muse, mutect2, varscan2
- RPS7 | c.456G>C p.R152= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV59233698; called by muse, mutect2, varscan2
- SMG7 | c.246G>A p.P82= | Silent (SNP) | VAF 26/234 reads (11%) | catalogued as rs372417959; called by muse, varscan2
- TPR | c.1203T>G p.A401= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs1456376624, COSV66606096; called by muse, mutect2, varscan2
- ZNF614 | c.912T>G p.A304= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV54548640; called by muse, mutect2
